CCDI case PBBTUE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/3ab5f0bb-76c2-45b6-9bb8-717c3c7ac9d0

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 0.4 years (162 days).

Biospecimens (3 samples)
- Sample 0DH5U8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH5VD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH5VR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
